Gene-level copy-number profile of tumor specimen CDDP-ABLQ-TTP2-B from CDDP_EAGLE case CDDP-ABLQ, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74 years.
Specimen CDDP-ABLQ-TTP2-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ea5ca9d7-5677-47f7-86f9-25af3482a8df.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABLQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/7b041969-5997-4750-b705-a6b02e1aa6d2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 41; copy number 1: 259; copy number 2: 7,473; copy number 3: 26,765; copy number 4: 11,241; copy number 5: 7,398; copy number 6: 4,476; copy number 7: 7; copy number 8: 728; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 40 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:69,433,255–69,435,409, 1 gene: LINC01758.
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr3:68,192,398–68,192,580, 1 gene (within-gene range 0–3): AC107626.1.
- chr3:103,630,661–103,630,912, 1 gene: TUBBP11.
- chr3:166,160,414–166,181,820, 4 genes: MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2.
- chr4:46,243,548–46,244,215, 1 gene: AC104072.1.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–1): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:95,868,667–95,868,764, 1 gene: RNU6-1059P.
- chr5:104,260,531–104,260,826, 1 gene: RN7SL255P.
- chr6:81,724,722–81,736,353, 1 gene (within-gene range 0–3): AL078599.2.
- chr6:85,257,328–85,257,694, 1 gene: AL122016.1.
- chr7:9,621,764–9,769,513, 1 gene (within-gene range 0–5): AC060834.2.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr8:46,822,174–46,907,309, 7 genes: LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3.
- chr10:65,271,319–65,315,080, 1 gene: AL592466.1.
- chr10:66,837,457–66,837,704, 1 gene (within-gene range 0–2): AL607023.1.
- chr10:106,140,143–106,188,722, 1 gene: LINC02624.
- chr11:59,391,354–59,392,292, 1 gene: OR5BB1P.
- chr11:81,552,226–81,556,425, 2 genes: MTND4LP18, MTND6P25.
- chr16:52,198,012–52,227,956, 1 gene: AC007333.2.
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.
- chr18:29,048,620–29,048,719, 1 gene: RNU6-408P.
- chr21:18,614,431–18,650,360, 1 gene (within-gene range 0–5): AF240627.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 737 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–17,503,923, 221 genes, copy number 7–9 (broad region; genes not listed).
- chr9:17,906,563–40,266,845, 450 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr9:40,233,923–40,234,029, 1 gene, copy number 8: RNU6-1269P.
- chr9:40,992,249–43,045,120, 61 genes, copy number 8 (broad region; genes not listed).
- chr13:61,805,150–62,029,572, 3 genes, copy number 8: RAC1P8, AL353765.1, LINC00358.
- chr17:60,810,165–60,811,462, 1 gene, copy number 7 (within-gene range 6–7): KRT18P61.

Autosomal genes at a single copy (total copy number 1): 257. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
